Surgical pathology report (de-identified scan), TCGA case TCGA-IB-AAUV, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-AAUV-01A (Primary Tumor).

[page 1 of 4]
CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected		Time Received	
Time Reported		Time Transmitted	
Order Number		Ordering Provider	
Status	Final	Relevant Information	
Copied To		Location	IGD-03
Report Patient	Name		Adenocarcinoma, duct NOS 850013
Demographics (for verification purposes)	Date of birth:		Date: Pancreas head C25.0
	Sex: M		ju 5/20/14

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number
Collected Date/Time
Received Date/Time
Pathologist
Specimen Description
A. Lymph nodes group A at
B. Gallbladder at
C. Whipple's specimen at
D. Portal lymph node at
E. Branch of superior mesenteric vein at
F. Retroperitoneal margin at
G. Mesocolon lymph nodes at
Clinical Information
Pancreatic cancer pancreatic head mass.
Infectious patient: No
Immunocompromised: No
History of neoplasm: No

Diagnosis

- A. Lymph Nodes, Group A, Resection:
- Five lymph nodes negative for carcinoma (0/5)
- B. Gallbladder, Cholecystectomy:
- Mild non-specific acute inflammation with marked eosinophilia.
- C. Duodenum and Pancreas, Pancreaticoduodenectomy (Whipple's):
- Head and uncinate process of the pancreas and common bile duct:
- Pancreatic moderately differentiated invasive ductal adenocarcinoma with mucinous features (see Comment).
- POSITIVE for perineural invasion.
- POSITIVE for lymph-vascular invasion.
- Foci of pancreatic intraepithelial neoplasia, grade 3 (PanIN 3).
- Common bile duct mucosa focally involved by carcinoma (i.e., cancerization).
- Vascular bed margin POSITIVE for carcinoma.
- Pancreatic resection margin negative for carcinoma, at least 0.6 cm away.
- Posterior resection margin negative for carcinoma, at least 0.15 cm away.
- Common bile duct resection margin negative for carcinoma.
- Three of fifteen peripancreatic lymph node POSITIVE for metastatic carcinoma (3/15).
- pT3N1Mx.
- Duodenum and distal stomach
- Ampullary region (submucosa, muscularis mucosa, and base of

[page 2 of 4]
- mucosa) involved by invasive carcinoma;
Distal duodenum ischemic changes, most likely related to the
surgery
- Distal and proximal resection margins free of tumor.
D. Portal lymph node, resection:
- Two lymph nodes negative for carcinoma (0/2).
E. Branch of superior mesenteric vein, resection:
- Negative for carcinoma.
F. Retroperitoneal margin, biopsy:
- Fragment of fibrous tissue and skeletal muscle, negative for carcinoma.
- One lymph node negative for carcinoma (0/1).
G. Mesocolon lymph nodes, resection:
- One of two lymph nodes POSITIVE for metastatic carcinoma (1/2) with extranodal extension.

Reported by:

Electronically signed by:

Verified:

Responsible Resident:

Synoptic Report

SPECIMEN:

Head of pancreas

Duodenum

Common bile duct

Gallbladder

PROCEDURE:

Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy

TUMOR SITE:

Pancreatic head

Uncinate process

TUMOR SIZE:

Greatest dimension: 4.8 cm

Additional dimensions: 3.6 x 2.2 cm cm

HISTOLOGIC TYPE:

Ductal adenocarcinoma

HISTOLOGIC GRADE:

G2: Moderately differentiated

MICROSCOPIC TUMOR EXTENSION:

Carcinoma in situ

Tumor invades ampulla of Vater or sphincter of Oddi

Tumor invades duodenal wall

Tumor invades peripancreatic soft tissues

Tumor invades retroperitoneal soft tissue

MARGINS:

Margins uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest margin: 1.5 mm

Specified margin: retroperitoneal

Margin(s) involved by invasive carcinoma

vascular bed margin

TREATMENT EFFECT (applicable to carcinomas treated with neoadjuvant therapy):

Not known

LYMPH-VASCULAR INVASION:

Present

PERINEURAL INVASION:

Present

PRIMARY TUMOR (pT):

pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery

REGIONAL LYMPH NODES (pN):

pN1: Regional lymph node metastasis

Number examined: 15

Number involved: 3

Gross Description

Received are specimen containers A to G. All requisitions and specimen containers are labelled with the patient's name, the cassettes and identifiers are labelled with the Surgical Number:

A. The specimen is received fresh and designated as "A - lymph node group A". The specimen consists of a single irregular piece of tan-yellow fibrofatty tissue (3.2 x 2.5 x 0.3 cm). Five possible lymph nodes are identified and range in size from 0.7 cm to 1.5 cm in greatest dimension. Cassettes submitted as follows:

[page 3 of 4]
- A1. largest lymph node bisected
- A2-3. two possible lymph nodes bisected, one inked blue
- B. The specimen is received fresh and designated as "B - gallbladder at The specimen consists of dusky grey, intact gallbladder (8.1 x 3.5 x 1.0 cm). The serosal surface is smooth and glistening. No identifiable nodules or abnormalities present. No cystic lymph nodes identified. On opening the gallbladder surface is light green and velvety with no identifiable calculi. There is a scant amount of thin green bile. Average wall thickness is 0.3 cm. Representative sections of the body, fundus, and cystic duct margin are submitted in cassette B1.
- C. The specimen is received fresh and designated as "C - whipple's specimen at The specimen consists of a whipple's procedure including proximal and distal duodenum, pancreatic head, and pancreatic uncinate process. No pyloric sphincter or gastric mucosa identified. Duodenum measures 21.2 cm in length and 6.5 cm in circumference. The distal 14.0 cm of duodenum is dusky and dark brown in color with sharp demarcation consistent with ischemia. The proximal portion is light tan-brown with regular plicae circulares extending from proximal to distal end. The bile duct extending to the ampulla of Vater is bisected and opened prior to fixation. The area surrounding ampulla of Vater is distinct from the surrounding duodenal mucosa. It is firm multinodular, dark-brown with irregular border extending roughly 3.1 x 2.2 cm with some contraction distorting the surrounding mucosal surface. Broad based nodules measure in size range from 0.2 to 0.5 cm in greatest diameter. The full length of common bile duct to the ampulla of Vater is 4.8 cm with an average diameter of 0.3 cm. Please note, the margins are inked as follows: Blue pancreatic resection margin, orange uncinate process, black vessel bed margin. The pancreatic resection margin measures 2.3 x 1.8 cm with central pancreatic duct (0.2 cm in diameter). The pancreatic duct can be probed only distally to a length of 1.8cm. Proximal portion was not identified. Combined the pancreas measures 5.6 x 4.8 x 2.7 cm. The cut surface of the common bile duct shows heterogenous light yellow, firm, irregular lesion extending 3.0 cm from the ampulla of Vater into the common bile duct involving the ampulla and duodenal submucosa. On cross sectioning, the tumor is solid, light-yellow, firm, with no obvious areas of necrosis or hemorrhage. The tumor seems to occupy the majority of uncinate process, head of the pancreas and grossly extends within 0.6 cm of the pancreatic resection margin and fully involves the common bile duct closest to the ampulla of Vater. The tumor itself, is poorly demarcated with a diffuse infiltrating border into the normal pancreatic parenchyma. Grossly, the tumor measures 4.8 x 3.6 x 2.2 cm. The specimen was photographed. The representative sections are submitted as follows:
- C1. bile duct resection margin
- C2-5. duodenum and ampulla of Vater, adjacent section taken in a longitudinal direction along the long axis of the common bile duct
- C6. duodenum and common bile duct, adjacent to the ampulla of Vater, transverse cross section to the direction of the common bile duct
- C7. cross section through duodenum, tumor, and common bile duct, transverse cross section to the direction of the common bile duct
- C8. transverse cross section at the ampulla of Vater immediately includes duodenum and common bile duct immediately contiguous with cassette C6
- C9. transverse cross section through duodenum, tumor, and the common bile duct, 0.5 cm away from C8 and is immediately contiguous with a section of C7
- C10. duodenum, tumor, and common bile duct transverse cross section approximately 0.5 cm away from cassette C9 and C7
- C11. transverse cross section through common bile duct 0.5 cm distal from cassette C10, includes vascular bed resection margin
- C12. representative cross section of duodenum and tumor immediately adjacent to C10-11
- C13. representative transverse section through retroperitoneal resection margin including uncinate process in orange
- C14-15. representative sections of the retroperitoneal resection margins, transverse including uncinate process inked in orange, sections contiguous
- C16. additional sections of the uncinate process immediately continuous with C13
- C17. additional transverse cross section through uncinate process, immediately continuous with C14 and C15
- C18-20. pancreatic resection margin inked blue adjacent perpendicular cross sections
- C21. proximal resection margin
- C22. representative section of proximal normal duodenum
- C23. representative section of normal distal duodenum
- C24. distal resection margin

[page 4 of 4]
- C25. representative section of grossly normal pancreatic parenchyma
C26. four anterior peripancreatic possible lymph nodes
C27. three anterior peripancreatic possible lymph nodes
C28. two possible anterior peripancreatic lymph nodes bisected, one inked blue
C29. two possible inferior lymph nodes
C30. one possible superior lymph node

Additional cassettes designated as follows:

- C31 to 33. additional vascular bed margins
C34. additional section of vascular bed margin

D. The specimen is received fresh and designated as "D - portal lymph node at .
The specimen consists of two pieces of dark grey to brown irregular piece of firm soft tissue. The larger fragment measures 1.5 x 1.6 x 0.5 cm. The smaller fragment measures 1.2 x 0.7 x 0.2 cm. The possible resection surface is present revealing the presence of a possible lymph node. The specimen is bisected and submitted in toto in cassettes D1 and D2.

E. The specimen is received fresh and designated as "E - branch of superior mesenteric vein at . The specimen consists of a single small fragment of tan-white firm tissue with no grossly identifiable features measuring 0.2 x 0.2 x 0.1 cm. Specimen is submitted in toto in cassette E1.

F. Single piece, irregular soft fibrous tissue, extensive cautery edge, red-pink. One suture present (cut away) 1.5 x 0.9 x 0.4 cm. Submitted in toto for

G. The specimen is received fresh and designated as "G - mesocolon lymph node". The specimen consists of a single irregular piece of tan grey to brown fibrofatty tissue (3.6 x 2.0 x 0.5 cm). Within the fibrofatty tissue are two possible lymph nodes with the largest measuring 2.0 cm and the second measuring 1.1 cm in greatest dimension. Both lymph nodes are bisected and the first large lymph node is bisected and submitted in G1. The smaller lymph node is bisected and submitted in G2.

Frozen Section Diagnosis

F. Retroperitoneal Margin:

- Negative for carcinoma. Conf #

Reported by:

Pathologist Comment

Invasive moderately differentiated ductal carcinoma of the pancreas arising in the background of PanIN3. Large cells with pleomorphic nuclei forming incomplete glands with mucinous features (<50%). Atypical mitoses present and extensive desmoplastic response. Adenocarcinoma involves duodenal muscularis mucosae, ampulla of Vater, and common bile duct with focal epithelial cancerization. Cancer invades within 0.6 cm of the pancreatic resection margin, 0.15 cm of the posterior resection margin, and is present at the vascular bed resection margin. Distal common bile duct is denuded of epithelium likely due to instrumentation (stent placement).

Accession Number
Encounter Number
Patient Location

Source: NCI Genomic Data Commons file fe215ab2-9325-4d7d-b04d-90d412136b39 (TCGA-IB-AAUV.3B060A4A-5A3D-4167-81B5-60C09D1769A8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).